Somatic mutation profile of tumor specimen TCGA-4R-AA8I-01A (aliquot TCGA-4R-AA8I-01A-11D-A382-10) from TCGA case TCGA-4R-AA8I, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-4R-AA8I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 674ac10b-102c-4cdb-ace5-6b37a9cbc4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4R-AA8I-10B (Blood Derived Normal), aliquot TCGA-4R-AA8I-10B-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f92aae5-f92b-4b92-b57f-0788c33a4e1d

The open-access MAF lists 1,240 somatic variants for this specimen: 969 protein-altering or splice-affecting, 249 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 751, Silent 249, Frame Shift Del 136, Nonsense Mutation 30, Frame Shift Ins 27, Splice Site 14, Splice Region 7, Intron 7, RNA 6, In Frame Del 4, 5'UTR 4, 3'UTR 3.

Variants (750 of 1,240; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.7857dup p.Q2620Tfs*17 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | catalogued as rs797045316; ClinVar: pathogenic; called by mutect2, varscan2
- COL1A1 | c.432del p.G145Dfs*120 | Frame Shift Del (DEL) | VAF 39/239 reads (16%) | catalogued as rs72667016, CD063493; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 65/174 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.344del p.K115Rfs*35 | Frame Shift Del (DEL) | VAF 64/232 reads (28%) | catalogued as rs1555980192; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GALK1 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371517491, CM993835; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934906, CM992178, COSV57651729; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 52/76 reads (68%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- VWF | c.4006C>T p.R1336* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs1565832211, CM1310552, COSV99778175; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99255356; called by muse, mutect2, varscan2
- AASS | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100741686; called by muse, mutect2, varscan2
- ABCA12 | c.3863C>T p.P1288L (on ENST00000272895 / NM_173076.3; = p.P970L on NM_015657.3) | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs1423599488, COSV55976768; called by muse, mutect2, varscan2
- ABCA9 | c.4748A>G p.Y1583C | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382678; called by muse, mutect2, varscan2
- ABCA9 | c.4396A>C p.T1466P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100382679; called by muse, mutect2, varscan2
- ABCB5 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV101295823; called by muse, mutect2
- ABCC1 | c.2281A>T p.I761F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100578693; called by muse, mutect2, varscan2
- ABCC10 | c.1408C>T p.R470W (on ENST00000372530 / NM_001198934.2; = p.R427W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751655535, COSV55088665; called by muse, mutect2, varscan2
- ABCC10 | c.2695C>T p.R899W (on ENST00000372530 / NM_001198934.2; = p.R871W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761231615, COSV55092291; called by muse, mutect2, varscan2
- ABCE1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs752956027, COSV99668401; called by muse, mutect2, varscan2
- ABHD2 | c.481A>G p.N161D | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV100756168; called by muse, mutect2, varscan2
- ABT1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 110/371 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs782604281, COSV99223078, COSV99223119; called by muse, mutect2, varscan2
- ACACA | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747343847; called by muse, mutect2, varscan2
- ACOT4 | c.1000T>C p.Y334H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1029860077, COSV100412789; called by muse, mutect2, varscan2
- ACTN3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138699570; called by muse, mutect2, varscan2
- ACVR2A | c.728A>T p.H243L | Missense Mutation (SNP) | VAF 86/119 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603987; called by muse, mutect2, varscan2
- ADAMTS16 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.811); catalogued as COSV99940223; called by muse, mutect2
- ADAMTSL5 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1366512261, COSV100389070; called by muse, mutect2, varscan2
- ADCY2 | c.1220C>A p.S407* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV100601920; called by muse, mutect2, varscan2
- ADGRF5 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51933841, COSV51936112, COSV99345013; called by muse, mutect2, varscan2
- ADGRL3 | c.3122T>C p.F1041S (on ENST00000506720 / NM_001322402.2; = p.F973S on NM_015236.6) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101546897; called by muse, mutect2
- ADNP2 | c.2507A>T p.E836V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100080571; called by muse, mutect2, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 97/188 reads (52%) | catalogued as rs1431558072; called by mutect2, varscan2
- AGGF1 | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1561287698, COSV100461557; called by muse, mutect2
- AGO3 | c.2573A>G p.Y858C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99868062; called by muse, mutect2
- AHDC1 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs746053039, COSV55943569; called by muse, mutect2, varscan2
- AHNAK | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs777477987, COSV99945845; called by muse, mutect2, varscan2
- AJM1 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99915474; called by muse, mutect2, varscan2
- ALAD | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1374282957, COSV99474593; called by muse, mutect2, varscan2
- ALDH16A1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs756830979, COSV53194076; called by muse, mutect2, varscan2
- ALDH1A1 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV99921099; called by muse, mutect2, varscan2
- ALOX5 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs28395872, COSV100979975; called by muse, mutect2, varscan2
- ALPK3 | c.4031A>G p.Y1344C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779689802, COSV99360279; called by muse, mutect2, varscan2
- AMOT | c.2027C>A p.A676D (on ENST00000371959 / NM_001113490.1; = p.A267D on NM_133265.3) | Missense Mutation (SNP) | VAF 69/92 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100494781; called by muse, mutect2, varscan2
- AMTN | c.330G>A p.Q110= | Splice Region (SNP) | VAF 87/240 reads (36%) | catalogued as COSV100219667; called by muse, mutect2, varscan2
- ANAPC11 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | catalogued as COSV100325922; called by muse, mutect2, varscan2
- ANAPC4 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100193835; called by muse, mutect2, varscan2
- ANKRD1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs758588912, COSV100865301; called by muse, mutect2, varscan2
- ANO6 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 207/503 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100262449; called by muse, mutect2, varscan2
- ANXA9 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV100929064; called by muse, mutect2, varscan2
- AP1B1 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs375168948; called by muse, varscan2
- AP2A2 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1216163460, COSV100172545; called by muse, mutect2, varscan2
- AP3B1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99670788; called by muse, mutect2, varscan2
- AP3B2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99916104, COSV99916559; called by muse, mutect2, varscan2
- AP5M1 | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99841067; called by muse, mutect2, varscan2
- APBA2 | c.2161T>A p.S721T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV101381954; called by muse, mutect2, varscan2
- APBB3 | c.1142G>T p.G381V (on ENST00000357560 / NM_133173.2; = p.G388V on NM_006051.3) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021172, COSV60053851; called by muse, mutect2, varscan2
- APBB3 | c.632+1G>T p.X211_splice | Splice Site (SNP) | VAF 44/171 reads (26%) | catalogued as rs770870465, COSV100021173; called by muse, mutect2, varscan2
- APOB | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99263890; called by muse, mutect2, varscan2
- APOE | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs752790054, COSV99375979; called by muse, mutect2, varscan2
- AQP6 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1565644200, COSV59645976; called by muse, mutect2, varscan2
- AQP6 | c.561+1G>T p.X187_splice | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100210083; called by muse, mutect2, varscan2
- ARAP1 | c.344del p.P115Hfs*39 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | catalogued as COSV100501985; called by mutect2, pindel, varscan2
- ARFGEF3 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs370057378, COSV99292029; called by muse, mutect2, varscan2
- ARHGAP11A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as COSV100853169; called by muse, mutect2, varscan2
- ARHGAP32 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV100087034; called by muse, mutect2, varscan2
- ARHGEF10 | c.1451C>T p.A484V (on ENST00000398564; = p.A459V on NM_014629.4) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144726787; called by muse, mutect2, varscan2
- ARHGEF10L | c.2840C>A p.A947D | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99392095; called by muse, mutect2, varscan2
- ARHGEF26 | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV100726401; called by muse, mutect2, varscan2
- ARHGEF28 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99708304; called by muse, mutect2
- ARHGEF28 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288359486, COSV55267329; called by muse, mutect2, varscan2
- ARID5A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs139848963, COSV62591023; called by muse, mutect2, varscan2
- ARMC3 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs867516472, COSV53067705, COSV99957550; called by muse, mutect2, varscan2
- ARRB1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV100758058; called by muse, mutect2, varscan2
- ASAP1 | c.960T>A p.N320K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100726884; called by muse, mutect2, varscan2
- ASB7 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); catalogued as rs749086577, COSV100235007; called by muse, mutect2, varscan2
- ASH1L | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV100853156; called by muse, mutect2, varscan2
- ASPM | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99659640; called by muse, mutect2, varscan2
- ATAD2 | c.3633T>A p.D1211E | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99784143; called by muse, mutect2, varscan2
- ATAD2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54881389, COSV54888536; called by muse, mutect2, varscan2
- ATG2B | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 26/377 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99951879, COSV99951952; called by muse, mutect2
- ATIC | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99377515; called by muse, mutect2, varscan2
- ATP1A2 | c.2929A>T p.M977L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.846); catalogued as COSV100767658; called by muse, mutect2, varscan2
- ATP4A | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs898108443, COSV52865537; called by muse, mutect2, varscan2
- ATRN | c.2174A>C p.D725A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV99496641; called by muse, mutect2, varscan2
- ATRN | c.3404A>G p.D1135G | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV53535712; called by muse, varscan2
- ATRX | c.3898A>G p.K1300E | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV100970163, COSV64873236; called by muse, mutect2, varscan2
- ATXN1 | c.858del p.S287Pfs*38 | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | catalogued as rs774055637, COSV104392095; called by mutect2, pindel, varscan2
- B3GAT2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 94/110 reads (85%) | catalogued as rs750513549, COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2, varscan2
- B3GNT5 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100191465; called by muse, mutect2, varscan2
- B3GNT6 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs782676328, COSV100845758; called by muse, mutect2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 33/137 reads (24%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAHCC1 | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 162/337 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs370431109; called by muse, mutect2, varscan2
- BAIAP2L1 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV50055987, COSV99133726; called by muse, mutect2, varscan2
- BCORL1 | c.4700A>G p.E1567G | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99498622; called by muse, mutect2, varscan2
- BORCS6 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV101197987; called by muse, mutect2, varscan2
- BPTF | c.1478A>G p.Y493C | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100074222; called by muse, mutect2, varscan2
- BROX | c.756+2T>C p.X252_splice | Splice Site (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100572076; called by muse, mutect2, varscan2
- BRWD3 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1337009699, COSV100955696; called by muse, mutect2, varscan2
- BTNL9 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100576100, COSV100576319; called by muse, mutect2, varscan2
- C1QA | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1043270464, COSV101009404; called by muse, mutect2, varscan2
- C1QTNF4 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV100209208; called by muse, mutect2, varscan2
- C1QTNF4 | c.118del p.L40Wfs*9 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | catalogued as rs747640589; called by mutect2, pindel, varscan2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs1283160262; called by mutect2, pindel, varscan2
- C1orf127 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs766680398, COSV100983419; called by muse, mutect2, varscan2
- C1orf174 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.53); catalogued as rs757932986, COSV100851719; called by muse, mutect2, varscan2
- C2CD3 | c.3584G>A p.R1195Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.073); catalogued as rs758046987, COSV58100412; called by muse, mutect2, varscan2
- C2CD4B | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV66791323; called by muse, mutect2, varscan2
- C9orf131 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs749997376, COSV56615026; called by muse, mutect2, varscan2
- C9orf135 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV101019726; called by muse, mutect2, varscan2
- CA11 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99320513; called by muse, mutect2, varscan2
- CA9 | c.104T>G p.V35G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100999778; called by muse, mutect2, varscan2
- CACFD1 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99390104; called by muse, mutect2, varscan2
- CACNA1B | c.1955C>A p.A652D | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99495497; called by muse, mutect2
- CACNA1B | c.2155A>G p.T719A | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99495499; called by muse, mutect2, varscan2
- CACNA1E | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs575157426, COSV62393390; called by muse, mutect2, varscan2
- CACNA2D1 | c.3247T>C p.Y1083H (on ENST00000356253 / NM_001366867.1; = p.Y1071H on NM_000722.4) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100666086, COSV100666716; called by muse, varscan2
- CADM2 | c.529G>A p.A177T (on ENST00000407528 / NM_001167674.2; = p.A179T on NM_153184.4) | Missense Mutation (SNP) | VAF 168/437 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.685); catalogued as rs771188436, COSV101053077; called by muse, varscan2
- CAPN15 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99562196; called by muse, varscan2
- CAPRIN2 | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs772253137, COSV51831005; called by muse, mutect2, varscan2
- CARMIL1 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs910881562, COSV100277026; called by muse, mutect2, varscan2
- CARMIL2 | c.1712A>G p.H571R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100575965; called by muse, mutect2, varscan2
- CARS1 | c.1952_1955del p.R651Kfs*32 | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | catalogued as rs1427767772; called by mutect2, pindel, varscan2
- CASZ1 | c.2128C>A p.L710M | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV100680818; called by muse, mutect2, varscan2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | catalogued as COSV100656585; called by mutect2, pindel, varscan2
- CBL | c.2324A>T p.D775V | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99875596; called by muse, mutect2, varscan2
- CBWD5 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 73/802 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1376176070; called by muse, varscan2
- CC2D1A | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs773188635, COSV58780974; called by muse, mutect2, varscan2
- CCDC158 | c.929A>T p.N310I | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101187164; called by muse, mutect2, varscan2
- CCDC39 | c.423A>C p.Q141H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99867442; called by muse, mutect2, varscan2
- CCDC74A | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.451); catalogued as COSV99723582; called by muse, varscan2
- CCDC74B | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.351); catalogued as COSV100134205; called by muse, mutect2, varscan2
- CCDC81 | c.1559A>G p.E520G (on ENST00000445632 / NM_001156474.2; = p.E430G on NM_021827.4) | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99563978; called by muse, mutect2, varscan2
- CCDC82 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99567097; called by muse, mutect2, varscan2
- CCL13 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187454526, COSV99861674; called by muse, mutect2, varscan2
- CCNT2 | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 102/146 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99750228; called by muse, mutect2, varscan2
- CCR3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs777668503, COSV100656355; called by muse, mutect2, varscan2
- CD226 | c.265A>G p.N89D | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); catalogued as COSV99710828; called by muse, mutect2
- CD40 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100953786; called by muse, mutect2, varscan2
- CDA | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906252; called by muse, mutect2, varscan2
- CDC42BPG | c.4600G>A p.V1534I | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.846); catalogued as COSV100711973; called by muse, mutect2, varscan2
- CDC7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs539320135, COSV52310602; called by muse, mutect2
- CDH10 | c.1068T>A p.D356E | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100050256; called by muse, mutect2, varscan2
- CDK9 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100953615; called by muse, mutect2, varscan2
- CDKN2C | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771853517, COSV52954362, COSV52954434; called by muse, mutect2, varscan2
- CDRT1 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV99887476; called by muse, mutect2, varscan2
- CEACAM5 | c.1802del p.P601Qfs*68 | Frame Shift Del (DEL) | VAF 56/178 reads (31%) | catalogued as rs782698410, COSV55750352; called by mutect2, pindel, varscan2
- CECR2 | c.2747G>T p.C916F (on ENST00000342247 / NM_001290047.2; = p.C733F on NM_001290046.1) | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs1292384319, COSV99376935; called by muse, mutect2, varscan2
- CELSR1 | c.4604A>G p.Y1535C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53094777; called by muse, mutect2, varscan2
- CELSR2 | c.3716A>G p.N1239S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99603167; called by muse, mutect2, varscan2
- CELSR3 | c.5707G>A p.G1903S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs778083864, COSV99372706; called by muse, mutect2, varscan2
- CEP126 | c.3007A>G p.T1003A | Missense Mutation (SNP) | VAF 216/494 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs1160580381, COSV99680625; called by muse, mutect2, varscan2
- CEP135 | c.2860T>C p.S954P | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs911801070, COSV99954156; called by muse, mutect2
- CEP89 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.123); catalogued as rs187160603, COSV59866221; called by muse, mutect2, varscan2
- CERS4 | c.468C>T p.H156= | Splice Region (SNP) | VAF 17/47 reads (36%) | catalogued as rs368700192; called by muse, mutect2, varscan2
- CERS5 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100451914; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 80/252 reads (32%) | catalogued as rs768479535; called by mutect2, varscan2
- CFAP46 | c.7261C>T p.P2421S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1045182377, COSV99584043; called by muse, mutect2
- CHAT | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs536359684, COSV100339822; called by muse, mutect2, varscan2
- CHD5 | c.2436+2T>C p.X812_splice | Splice Site (SNP) | VAF 40/110 reads (36%) | catalogued as COSV99312630; called by muse, mutect2, varscan2
- CHEK1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs761313560, COSV54022462; called by muse, mutect2, varscan2
- CHGA | c.695A>C p.E232A | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.746); catalogued as COSV99381002; called by muse, mutect2, varscan2
- CHRNB2 | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100872549; called by muse, mutect2, varscan2
- CHST3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100910399; called by muse, mutect2, varscan2
- CHST8 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs557313187, COSV99380740; called by muse, mutect2, varscan2
- CIPC | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.69); catalogued as rs201665496, COSV62377023; called by muse, mutect2, varscan2
- CISH | c.197A>G p.D66G (on ENST00000348721 / NM_145071.4; = p.D83G on NM_013324.6) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100811734; called by muse, mutect2, varscan2
- CIT | c.4234G>A p.G1412S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370080702; called by muse, mutect2, varscan2
- CLCNKB | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100990195; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLP1 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100239754, COSV57055608; called by muse, mutect2, varscan2
- CLPTM1L | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100306846; called by muse, mutect2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CMYA5 | c.9094T>A p.S3032T | Missense Mutation (SNP) | VAF 174/422 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1379444360, COSV101483885; called by muse, mutect2, varscan2
- CNGB1 | c.3570del p.E1191Sfs*33 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs769866157; called by mutect2, pindel, varscan2
- CNGB1 | c.2707T>C p.Y903H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs924004848, COSV99201616; called by muse, mutect2, varscan2
- CNPY4 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99498760; called by muse, mutect2, varscan2
- COBL | c.3282del p.K1094Nfs*20 | Frame Shift Del (DEL) | VAF 48/157 reads (31%) | catalogued as rs1562810271; called by mutect2, pindel, varscan2
- COBLL1 | c.1695A>C p.E565D (on ENST00000392717; = p.E527D on NM_014900.5) | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV99527418; called by muse, mutect2, varscan2
- COL15A1 | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100897449; called by muse, mutect2
- COL4A1 | c.359del p.P120Qfs*36 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | catalogued as rs1566378788, COSV65422277; called by mutect2, pindel, varscan2
- COL6A1 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1241461198, COSV100719971; called by muse, mutect2, varscan2
- COL6A2 | c.2542A>G p.N848D | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99384700; called by muse, mutect2, varscan2
- COL7A1 | c.7987del p.E2663Sfs*16 | Frame Shift Del (DEL) | VAF 73/190 reads (38%) | catalogued as CM096538; called by mutect2, pindel, varscan2
- COL9A2 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199502479, COSV101028391, COSV65624414; called by muse, mutect2, varscan2
- COQ8B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs781221940, COSV99648499; called by muse, mutect2, varscan2
- CPA3 | c.585A>C p.K195N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV99935988; called by muse, mutect2, varscan2
- CPNE2 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99321266; called by muse, mutect2, varscan2
- CPNE6 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV99393159; called by muse, varscan2
- CPT2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99598053; called by muse, mutect2, varscan2
- CR2 | c.2294A>T p.D765V | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100889537; called by muse, mutect2, varscan2
- CRACD | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51718557, COSV99948870; called by muse, mutect2, varscan2
- CRYGC | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs756143605, COSV99965251; called by muse, mutect2, varscan2
- CSMD2 | c.5770C>T p.R1924C | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761223081, COSV99586648; called by muse, mutect2, varscan2
- CSMD2 | c.5272C>T p.R1758C | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs773685292, COSV99586657; called by muse, mutect2, varscan2
- CSTF1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1407318272, COSV53859158; called by muse, mutect2, varscan2
- CSTF2T | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100484091; called by muse, mutect2, varscan2
- CTDP1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs777446741, COSV50002993; called by muse, mutect2, varscan2
- CTHRC1 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100372926; called by muse, mutect2, varscan2
- CTNNA1 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV57081940; called by muse, mutect2, varscan2
- CUBN | c.10289A>G p.N3430S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV100912130; called by muse, mutect2
- CUL9 | c.7112A>G p.N2371S | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99334859; called by muse, mutect2, varscan2
- CYFIP1 | c.3755G>A p.S1252N | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100487832; called by muse, mutect2, varscan2
- DARS1 | c.49A>T p.I17F | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99927351; called by muse, mutect2, varscan2
- DAZL | c.150+2T>C p.X50_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99167468; called by muse, mutect2, varscan2
- DCAF13 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99885050; called by muse, mutect2, varscan2
- DCTD | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762837387, COSV63866847; called by muse, mutect2, varscan2
- DDB2 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs1309579140, COSV99921466; called by muse, mutect2
- DDX1 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450410081, COSV51838903; called by muse, mutect2, varscan2
- DDX39B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV63331775; called by muse, varscan2
- DDX3Y | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 111/136 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV60177409; called by muse, mutect2, varscan2
- DENND2B | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100567181; called by muse, mutect2, varscan2
- DENND4B | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100768464; called by muse, mutect2, varscan2
- DENND5A | c.3857A>C p.D1286A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100064139; called by muse, mutect2, varscan2
- DGKG | c.1426T>G p.L476V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs983291969, COSV99402569; called by muse, mutect2
- DIABLO | c.328G>A p.A110T (on ENST00000443649 / NM_001278303.1; = p.A183T on NM_019887.6) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as rs781358968, COSV99928046; called by muse, mutect2, varscan2
- DIAPH1 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99525935; called by muse, mutect2, varscan2
- DNAH1 | c.10718A>T p.D3573V | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV101324865; called by muse, mutect2, varscan2
- DNAH10 | c.11149del p.A3717Pfs*13 (on ENST00000409039; = p.A3656Pfs*13 on NM_207437.3) | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as COSV101291861; called by mutect2, pindel, varscan2
- DNAH2 | c.3274A>T p.I1092F | Missense Mutation (SNP) | VAF 136/201 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101209043; called by muse, mutect2, varscan2
- DNAH5 | c.1644+2T>G p.X548_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99445669; called by muse, mutect2, varscan2
- DNAJB13 | c.368T>A p.L123* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100334446; called by muse, mutect2, varscan2
- DNAJC11 | c.1460A>G p.D487G | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99275463; called by muse, mutect2, varscan2
- DNAJC21 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs753741966, COSV57762895; called by muse, mutect2, varscan2
- DOCK2 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99910543; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK4 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs755355579, COSV70321983, COSV70324527; called by muse, mutect2, varscan2
- DOP1B | c.2038A>G p.N680D | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV101215092; called by muse, mutect2, varscan2
- DOT1L | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757113225, COSV101288525; called by muse, mutect2, varscan2
- DRC1 | c.1898T>C p.V633A | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV99716704; called by muse, mutect2, varscan2
- DTX2 | c.1372T>C p.Y458H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100184393; called by muse, mutect2, varscan2
- DTX3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.012); catalogued as rs373278710; called by muse, mutect2, varscan2
- DUOXA1 | c.206-1G>A p.X69_splice | Splice Site (SNP) | VAF 23/126 reads (18%) | catalogued as COSV99972870; called by muse, mutect2, varscan2
- DUSP18 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs775345868, COSV100588813, COSV58180723; called by muse, mutect2, varscan2
- DUSP29 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs190150687, COSV58299971; called by muse, mutect2, varscan2
- DVL1 | c.1441C>T p.R481W (on ENST00000378888 / NM_001330311.2; = p.R456W on NM_004421.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs970301024, COSV100229288; called by muse, mutect2, varscan2
- DVL2 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372746877; called by muse, mutect2, varscan2
- DYSF | c.1262A>C p.E421A | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99244736; called by muse, mutect2, varscan2
- DYSF | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs761279290, COSV50445122; called by muse, mutect2, varscan2
- DZANK1 | c.2080G>A p.A694T (on ENST00000262547 / NM_001099407.1; = p.A501T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs758691948, COSV52749392, COSV52750149; called by muse, mutect2, varscan2
- DZIP1 | c.2161G>A p.A721T (on ENST00000347108; = p.A702T on NM_014934.5) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100714014; called by muse, mutect2, varscan2
- DZIP1 | c.1090A>G p.M364V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1489638336, COSV100714015; called by muse, mutect2, varscan2
- E4F1 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); catalogued as rs768604168, COSV57040746; called by muse, mutect2, varscan2
- ECM2 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs781440673, COSV60741607; called by muse, mutect2, varscan2
- ECPAS | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs768257099, COSV99397625; called by muse, mutect2, varscan2
- EDC3 | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.531); catalogued as rs753183030, COSV100165800; called by muse, mutect2, varscan2
- EDEM2 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as rs763413780, COSV100993659; called by muse, mutect2, varscan2
- EDEM3 | c.1124T>C p.L375S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100544937; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB5 | c.4138C>T p.R1380C | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs754404201, COSV57926755; called by muse, mutect2, varscan2
- EFCAB6 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs770841643, COSV99412557; called by muse, mutect2, varscan2
- EGLN2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs140368149; called by muse, mutect2, varscan2
- EHD1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1462494316, COSV100276872; called by muse, mutect2, varscan2
- EIF2A | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770906744, COSV53526384; called by muse, mutect2, varscan2
- EIF2B2 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as COSV99837631; called by muse, mutect2, varscan2
- ELAC2 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100568361; called by muse, mutect2, varscan2
- ELAC2 | c.4T>C p.W2R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100568364; called by muse, mutect2, varscan2
- ELK3 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99957496; called by muse, mutect2, varscan2
- EME1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV99868828; called by muse, mutect2, varscan2
- EML3 | c.2258-2A>C p.X753_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99604042; called by muse, mutect2, varscan2
- ENGASE | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 183/242 reads (76%) | catalogued as rs1299603925, COSV100285667; called by muse, mutect2, varscan2
- ENOSF1 | c.1310G>A p.R437Q (on ENST00000340116 / NM_001354066.2; = p.R403Q on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1295937924, COSV99200973, COSV99201106; called by muse, mutect2, varscan2
- ENOX1 | c.1471T>G p.L491V | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99815148; called by muse, mutect2, varscan2
- EPC1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV53925685; called by muse, mutect2, varscan2
- EPHA3 | c.1872T>A p.D624E | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.96); catalogued as rs1162005172, COSV100343293; called by muse, varscan2
- EPHA8 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.845); catalogued as rs139543017; called by muse, mutect2, varscan2
- EPHB2 | c.1025T>A p.L342Q | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101006790; called by muse, mutect2, varscan2
- EPPK1 | c.4864A>T p.K1622* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV101599748; called by muse, mutect2, varscan2
- EPS8L1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373089208; called by muse, mutect2, varscan2
- EPS8L2 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100585339; called by muse, mutect2, varscan2
- ERCC4 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777184889, COSV61314123; called by muse, mutect2, varscan2
- ERO1A | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 179/441 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101193573; called by muse, mutect2, varscan2
- ERO1B | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100523924; called by muse, mutect2
- ESR1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52789083, COSV99237922; called by muse, mutect2, varscan2
- ESRP1 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.207); catalogued as COSV100619197; called by muse, mutect2
- ETFDH | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 138/353 reads (39%) | catalogued as COSV100309790; called by muse, mutect2, varscan2
- EXOSC10 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100442182; called by muse, mutect2, varscan2
- FAM117A | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.736); catalogued as rs199525619, COSV53633514; called by muse, mutect2, varscan2
- FAM13A | c.1523T>C p.M508T | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as COSV99982942; called by muse, mutect2, varscan2
- FAM171B | c.1427A>G p.N476S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100488306; called by muse, mutect2
- FAM83H | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 520/1225 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs371078447; called by muse, mutect2, varscan2
- FAM90A1 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV100274206; called by muse, mutect2
- FAM98A | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV99479066; called by muse, mutect2, varscan2
- FASTK | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99879565; called by muse, mutect2, varscan2
- FASTKD1 | c.1827T>A p.D609E | Missense Mutation (SNP) | VAF 228/321 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.127); catalogued as COSV101494273; called by muse, varscan2
- FASTKD1 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 107/141 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs540349050, COSV71624907; called by muse, mutect2, varscan2
- FASTKD3 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs756188535, COSV99241345; called by muse, mutect2, varscan2
- FAT4 | c.14279C>T p.A4760V | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as COSV100627361; called by muse, mutect2, varscan2
- FBN1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1310736674, COSV57310797; called by muse, mutect2, varscan2
- FBXO25 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99366768; called by muse, mutect2
- FBXW2 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100535098; called by muse, mutect2, varscan2
- FBXW7 | c.2036A>G p.N679S (on ENST00000281708 / NM_001349798.2; = p.N599S on NM_018315.5) | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99654814; called by muse, mutect2, varscan2
- FCGR1A | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 46/251 reads (18%) | catalogued as COSV100977262; called by muse, mutect2, varscan2
- FCN3 | c.566A>T p.N189I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV99585244; called by muse, mutect2, varscan2
- FCRL1 | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100839728; called by muse, mutect2, varscan2
- FCRL3 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942889; called by muse, mutect2, varscan2
- FDPS | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV100756102; called by muse, mutect2, varscan2
- FEN1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573495657, COSV57250794; called by muse, mutect2, varscan2
- FGD4 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV99846806; called by muse, mutect2, varscan2
- FH | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100844980; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs774060142; called by mutect2, varscan2
- FLRT3 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99427828; called by muse, mutect2, varscan2
- FN1 | c.3621A>T p.R1207S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116267; called by muse, mutect2, varscan2
- FOXE1 | c.822del p.S275Pfs*92 | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | catalogued as rs751660227; called by mutect2, pindel, varscan2
- FOXH1 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100023567; called by muse, mutect2, varscan2
- FUT1 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV99711376; called by muse, mutect2, varscan2
- FYCO1 | c.2252A>G p.K751R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99945217; called by muse, mutect2, varscan2
- FZD5 | c.480dup p.R161Qfs*108 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | catalogued as rs1413162495; called by mutect2, pindel, varscan2
- GAB2 | c.1993C>T p.R665W (on ENST00000361507 / NM_080491.3; = p.R627W on NM_012296.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747450985, COSV60867726; called by muse, mutect2, varscan2
- GALK2 | c.829A>T p.I277F | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100508639; called by muse, mutect2, varscan2
- GALR2 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100134888; called by muse, mutect2, varscan2
- GAS2L1 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as rs768501433, COSV99329410; called by muse, mutect2, varscan2
- GATAD2B | c.1566A>G p.I522M | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100897822; called by muse, mutect2, varscan2
- GATB | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs766660548, COSV56133615; called by muse, mutect2, varscan2
- GDI2 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs376781352; called by muse, mutect2, varscan2
- GGA1 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100289653; called by muse, mutect2, varscan2
- GGCX | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV99289669; called by muse, varscan2
- GGT5 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV99571287; called by muse, mutect2, varscan2
- GINS4 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99394454; called by muse, mutect2, varscan2
- GJA4 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs757382942, COSV60726362; called by muse, mutect2, varscan2
- GJA5 | c.1011T>A p.Y337* | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as COSV99605368; called by muse, mutect2, varscan2
- GJB4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs748172389, COSV58356610; called by muse, mutect2, varscan2
- GJD2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs113904860, COSV51749372; called by muse, mutect2, varscan2
- GK5 | c.895A>T p.T299S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV101242102; called by muse, mutect2, varscan2
- GLI2 | c.2605C>T p.Q869* (on ENST00000361492 / NM_001374353.1; = p.Q886* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 62/146 reads (42%) | catalogued as COSV100082470; called by muse, mutect2, varscan2
- GLIS3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs774124083, COSV100173366; called by muse, mutect2, varscan2
- GLRA3 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56870148, COSV99927070; called by muse, mutect2
- GNAZ | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99320479; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 74/272 reads (27%) | catalogued as rs768760517; called by mutect2, varscan2
- GPATCH2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.289); catalogued as rs1395136941, COSV65130152; called by muse, mutect2, varscan2
- GPATCH2 | c.506T>A p.V169E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100861353; called by muse, mutect2, varscan2
- GPC2 | c.1047dup p.D350Rfs*148 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as rs748011069; called by mutect2, varscan2
- GPR83 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99703574; called by muse, mutect2, varscan2
- GPR87 | c.231A>G p.I77M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99608699; called by muse, mutect2, varscan2
- GPRIN1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs764198142, COSV56139472; called by muse, mutect2, varscan2
- GPSM1 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as rs1352021155, COSV61303275; called by muse, mutect2, varscan2
- GRIA1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766140803, COSV53598986; called by muse, mutect2, varscan2
- GRIN2C | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV99500616; called by muse, mutect2, varscan2
- GRIN3A | c.2956T>A p.S986T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100701382; called by muse, mutect2, varscan2
- GRK3 | c.1326C>T p.G442= | Splice Region (SNP) | VAF 55/127 reads (43%) | catalogued as rs778579878, COSV60793677; called by muse, mutect2, varscan2
- GSK3A | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725090; called by muse, mutect2
- GTF2H4 | c.1380T>G p.H460Q | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99461516; called by muse, mutect2, varscan2
- GUSB | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100512511; called by muse, mutect2
- H4C11 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV100747941; called by muse, mutect2, varscan2
- H4C9 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100574868; called by muse, mutect2, varscan2
- HAND2 | c.41A>G p.H14R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as COSV100854149; called by muse, mutect2, varscan2
- HCLS1 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100100379; called by muse, mutect2, varscan2
- HDAC4 | c.1976A>G p.D659G | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV100612753; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HDAC5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs772611618, COSV56821579; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HDHD5 | c.398G>A p.R133Q (on ENST00000336737 / NM_033070.3; = p.R103Q on NM_017829.5) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs141580777, COSV99324519; called by muse, mutect2, varscan2
- HDLBP | c.3023T>C p.V1008A | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100189997; called by muse, mutect2, varscan2
- HEPACAM | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100005491; called by muse, mutect2, varscan2
- HMGCR | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99843055; called by muse, mutect2, varscan2
- HNRNPL | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs749828786, COSV99670042; called by muse, mutect2, varscan2
- HOXB13 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99285106; called by muse, mutect2, varscan2
- HSD17B13 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100143083; called by muse, mutect2
- HTT | c.9242G>C p.G3081A | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100750462; called by muse, mutect2, varscan2
- IARS1 | c.1910A>G p.N637S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV100986782; called by muse, mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 40/74 reads (54%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- ICAM5 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703152; called by muse, mutect2, varscan2
- IFFO1 | c.1201G>A p.E401K (on ENST00000396840 / NM_001330324.2; = p.E404K on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs760163963, COSV100350836; called by muse, mutect2, varscan2
- IGSF9 | c.3447C>A p.F1149L (on ENST00000368094 / NM_001135050.2; = p.F1133L on NM_020789.4) | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100230986; called by muse, mutect2, varscan2
- IGSF9B | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV100317088, COSV100318293; called by muse, mutect2, varscan2
- IKZF1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58792054; called by muse, mutect2, varscan2
- IL17C | c.146del p.P49Hfs*16 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | catalogued as rs773521874; called by mutect2, pindel, varscan2
- IL17RA | c.1063T>A p.Y355N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100082898; called by muse, mutect2, varscan2
- IL23A | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV57336014; called by muse, mutect2, varscan2
- IL9R | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.944); catalogued as COSV99729334; called by muse, mutect2
- INAVA | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557970148, COSV100949885; called by muse, mutect2, varscan2
- INSRR | c.2809C>A p.L937I | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as COSV100947199; called by muse, mutect2, varscan2
- INTS1 | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 138/260 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as rs1466625171, COSV67178352; called by muse, mutect2, varscan2
- INVS | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as rs370949695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCC | c.1167del p.P390Qfs*80 | Frame Shift Del (DEL) | VAF 120/278 reads (43%) | catalogued as rs753907631; called by mutect2, varscan2
- ISLR2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV62302446, COSV62303049; called by muse, mutect2, varscan2
- ITGA4 | c.2827T>C p.F943L | Missense Mutation (SNP) | VAF 177/260 reads (68%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100183207; called by muse, varscan2
- ITGB3 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101457550; called by muse, mutect2, varscan2
- ITIH3 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs773229579, COSV69649186, COSV69650925; called by muse, mutect2, varscan2
- ITIH5 | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99903847; called by muse, mutect2, varscan2
- ITPR3 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966977; called by muse, mutect2, varscan2
- JAG1 | c.3647A>G p.Y1216C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99652486; called by muse, mutect2, varscan2
- JARID2 | c.1186dup p.A396Gfs*25 | Frame Shift Ins (INS) | VAF 73/205 reads (36%) | catalogued as rs778734711; called by mutect2, varscan2
- JCHAIN | c.44T>A p.I15N | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99636300; called by muse, mutect2
- KANSL1 | c.3268C>T p.R1090W (on ENST00000574590 / NM_001193465.2; = p.R1091W on NM_015443.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as rs922454072, COSV52240861; called by muse, mutect2, varscan2
- KATNIP | c.2462A>G p.N821S | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as rs1567378343, COSV99850011; called by muse, mutect2, varscan2
- KCNK17 | c.503del p.G168Afs*61 | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | catalogued as COSV64685346; called by mutect2, pindel, varscan2
- KCNMB2 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs769870548, COSV64201378; called by muse, mutect2, varscan2
- KCNMB4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1289045846, COSV50690679, COSV50690910; called by muse, mutect2, varscan2
- KCTD18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs543025211, COSV63344171; called by muse, mutect2, varscan2
- KDM4B | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 144/166 reads (87%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs374489612; called by muse, varscan2
- KDM6A | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV65048386; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 48/91 reads (53%) | catalogued as rs747555402; called by mutect2, pindel, varscan2
- KIF20A | c.1759C>G p.H587D | Missense Mutation (SNP) | VAF 9/292 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1185333526, COSV101203088; called by muse, mutect2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 72/166 reads (43%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF20B | c.4769A>T p.E1590V (on ENST00000371728 / NM_001284259.2; = p.E1550V on NM_016195.4) | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99589566; called by muse, mutect2, varscan2
- KIFC3 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101109100; called by muse, mutect2, varscan2
- KIRREL2 | c.1928A>G p.N643S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99383628; called by muse, mutect2, varscan2
- KLHL4 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 161/233 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV100909197; called by muse, mutect2, varscan2
- KLK10 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399836; called by muse, mutect2, varscan2
- KMT2A | c.10705A>G p.I3569V | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV100628102; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2D | c.10640G>A p.R3547H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775632051, COSV56420120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPRP | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs201616422, COSV64221035; called by muse, mutect2, varscan2
- KRT2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100548306; called by muse, mutect2, varscan2
- KRT20 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs377652428; called by muse, mutect2, varscan2
- KRT20 | c.313T>G p.W105G | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99391322; called by muse, mutect2
- KRT31 | c.818T>A p.I273N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99289433; called by muse, mutect2, varscan2
- KTN1 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101255008; called by muse, mutect2, varscan2
- L1CAM | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 69/97 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100648890; called by muse, mutect2, varscan2
- LAMA5 | c.9463A>C p.S3155R | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV99438316; called by muse, mutect2, varscan2
- LAP3 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99884065; called by muse, mutect2, varscan2
- LDLR | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs139507589, CM0910342; called by muse, mutect2, varscan2
- LENG8 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV100457167; called by muse, mutect2, varscan2
- LGI2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as rs774450493, COSV101180774; called by muse, mutect2, varscan2
- LGMN | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762702370, COSV100605731; called by muse, mutect2, varscan2
- LIG3 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99252224; called by muse, mutect2, varscan2
- LIG3 | c.2743G>T p.V915L | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99252228; called by muse, mutect2, varscan2
- LILRB3 | c.1702G>A p.A568T (on ENST00000346401; = p.A556T on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV99557186; called by muse, mutect2, varscan2
- LILRB5 | c.1762dup p.L588Pfs*63 (on ENST00000449561 / NM_001081442.3; = p.L587Pfs*63 on NM_006840.5) | Frame Shift Ins (INS) | VAF 33/115 reads (29%) | catalogued as rs775329343; called by mutect2, pindel, varscan2
- LINGO1 | c.39G>T p.R13S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100796292; called by muse, mutect2
- LINGO3 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1287949527, COSV101347216; called by muse, mutect2, varscan2
- LIPE | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs201302932, COSV54924367; called by muse, mutect2, varscan2
- LLGL1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as rs1413321606, COSV100375094; called by muse, mutect2, varscan2
- LMBR1 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100626553; called by muse, mutect2, varscan2
- LMNTD2 | c.1886A>G p.D629G | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99529583; called by muse, mutect2, varscan2
- LMTK2 | c.4438A>T p.S1480C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99806127; called by muse, mutect2, varscan2
- LRP1 | c.2331del p.T778Lfs*2 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as rs34108076; called by mutect2, pindel, varscan2
- LRP1B | c.9542T>A p.I3181K | Missense Mutation (SNP) | VAF 95/125 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101253400; called by muse, mutect2, varscan2
- LRP6 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143966208, COSV53784596; called by muse, mutect2, varscan2
- LRRC14 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs748837708, COSV99467109; called by muse, varscan2
- LRRC14 | c.1174T>C p.C392R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1422184680, COSV99467110; called by muse, mutect2, varscan2
- LRRC24 | c.106T>C p.C36R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99430349; called by muse, mutect2, varscan2
- LRRC37A3 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1187566783, COSV59759845; called by mutect2, varscan2
- LRRC40 | c.1555A>T p.T519S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100918713; called by muse, mutect2, varscan2
- LRRC7 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV100199177; called by muse, mutect2, varscan2
- LRRK2 | c.2262T>A p.S754R | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as rs199929255, COSV100109382; called by muse, mutect2, varscan2
- LRRTM2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs370649836, COSV99217678; called by muse, mutect2, varscan2
- LRTM1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs372086680, COSV55520410; called by muse, mutect2, varscan2
- LTBP1 | c.2966G>A p.R989H (on ENST00000404816 / NM_206943.4; = p.R663H on NM_000627.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs142262862, COSV100616468, COSV100616933; called by muse, mutect2, varscan2
- LTK | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1310595333, COSV99778619; called by muse, mutect2, varscan2
- LUM | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99898902; called by muse, mutect2, varscan2
- LYNX1 | c.125T>C p.M42T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.43); catalogued as COSV100235440; called by muse, mutect2, varscan2
- LZTS2 | c.979T>C p.C327R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1343863511, COSV100932097; called by muse, mutect2
- M1AP | c.1256A>G p.H419R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV51844938, COSV99283952; called by muse, mutect2, varscan2
- MACF1 | c.12514A>G p.T4172A (on ENST00000372915; = p.T2105A on NM_012090.5) | Missense Mutation (SNP) | VAF 64/227 reads (28%) | catalogued as COSV99241682; called by muse, mutect2, varscan2
- MAGIX | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT tolerated (0.39); PolyPhen benign (0.146); catalogued as COSV66256785; called by muse, mutect2, varscan2
- MAK | c.1749dup p.Q584Afs*8 | Frame Shift Ins (INS) | VAF 25/117 reads (21%) | catalogued as rs1561922707; called by mutect2, pindel, varscan2
- MAP1A | c.7082G>A p.G2361D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV100288171; called by muse, mutect2, varscan2
- MAP3K9 | c.2221C>T p.R741W (on ENST00000554752 / NM_001284230.1; = p.R755W on NM_033141.4) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs145221753; called by muse, mutect2, varscan2
- MAP4K2 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs774975786, COSV99580469; called by muse, mutect2, varscan2
- MAPK8 | c.615C>T p.N205= | Splice Region (SNP) | VAF 7/98 reads (7%) | catalogued as rs1037196002, COSV100827380; called by muse, mutect2
- MBOAT1 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100208442; called by muse, mutect2, varscan2
- MCF2L | c.598G>A p.V200I (on ENST00000375608; = p.V168I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs563320301, COSV100982159; called by muse, mutect2, varscan2
- MED13L | c.4957G>A p.V1653I | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs151181388; called by muse, mutect2, varscan2
- MED17 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV99315757; called by muse, mutect2, varscan2
- MED24 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100673012, COSV62418583; called by muse, mutect2, varscan2
- MEFV | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as rs375665850, COSV54821024; called by muse, mutect2
- MEGF8 | c.7321T>C p.C2441R (on ENST00000251268 / NM_001271938.2; = p.C2374R on NM_001410.3) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99234668; called by muse, mutect2, varscan2
- MFGE8 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1318710823, COSV99183941; called by muse, mutect2
- MGARP | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as rs1382515685, COSV101299197; called by muse, mutect2, varscan2
- MGAT4A | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV99383985; called by muse, varscan2
- MICALL1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99317040; called by muse, mutect2, varscan2
- MIEF1 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100307562; called by muse, mutect2, varscan2
- MIIP | c.463-2A>G p.X155_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99337399; called by muse, mutect2
- MMP17 | c.319A>C p.T107P | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100861867; called by muse, mutect2, varscan2
- MMP20 | c.498T>A p.D166E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99497464; called by muse, mutect2, varscan2
- MON2 | c.2549A>G p.N850S | Missense Mutation (SNP) | VAF 147/372 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1354248424, COSV99741744; called by muse, mutect2, varscan2
- MORN1 | c.241T>C p.W81R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.393); catalogued as COSV100087740; called by muse, mutect2, varscan2
- MPDZ | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061015; called by muse, mutect2, varscan2
- MPP3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs762773671, COSV68198634; called by muse, mutect2, varscan2
- MPPED2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100813111, COSV63901358; called by muse, mutect2, varscan2
- MRGPRF | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.988); catalogued as rs755456887, COSV57995901; called by muse, mutect2, varscan2
- MRPL2 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99431434; called by muse, mutect2, varscan2
- MSLN | c.699del p.Y234Tfs*78 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs1304207931; called by mutect2, pindel, varscan2
- MTHFD1 | c.2584A>C p.I862L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV99386597; called by muse, mutect2, varscan2
- MTHFR | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453489; called by muse, mutect2, varscan2
- MTMR2 | c.1084T>A p.S362T | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100656580; called by muse, mutect2, varscan2
- MTR | c.34+2T>C p.X12_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as rs776165231, COSV100855796; called by muse, mutect2, varscan2
- MUC6 | c.7025C>T p.T2342M | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.32); catalogued as rs779736305, COSV59958726; called by muse, mutect2, varscan2
- MYH1 | c.3743A>G p.N1248S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs200591032, COSV99875023; called by muse, mutect2, varscan2
- MYH1 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs761774573, COSV99874768, COSV99875026; called by muse, mutect2, varscan2
- MYH14 | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759824498, COSV51815031; called by muse, mutect2, varscan2
- MYH7B | c.5516G>A p.R1839H | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs747498123, COSV99327872; called by muse, mutect2, varscan2
- MYO7A | c.5972T>C p.V1991A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101289054; called by muse, mutect2, varscan2
- MYO9A | c.259A>T p.M87L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.053); catalogued as rs773354744, COSV100612747; called by muse, mutect2, varscan2
- NAALADL1 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs756376050, COSV60524970; called by muse, mutect2, varscan2
- NAB1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs769154499, COSV100492889; called by muse, mutect2, varscan2
- NAGLU | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as COSV99864004; called by muse, mutect2, varscan2
- NANP | c.90+2T>A p.X30_splice | Splice Site (SNP) | VAF 45/132 reads (34%) | catalogued as COSV100504985; called by muse, mutect2, varscan2
- NAV1 | c.2410G>A p.V804I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV99818296; called by muse, mutect2, varscan2
- NAV2 | c.6244G>A p.V2082I (on ENST00000396087 / NM_001244963.2; = p.V2023I on NM_145117.5) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.8); catalogued as rs770741708, COSV100216260; called by muse, mutect2, varscan2
- NBEA | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100077211; called by muse, mutect2, varscan2
- NBEAL2 | c.6614G>T p.R2205L | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52764826; called by muse, mutect2
- NCOA6 | c.3895A>G p.T1299A | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100749919; called by muse, varscan2
- NDST1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs141135213; called by muse, mutect2, varscan2
- NEIL3 | c.1769T>C p.F590S | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52813809, COSV99220036; called by muse, mutect2, varscan2
- NEK8 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as COSV99261579; called by muse, mutect2, varscan2
- NEU2 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs764112832, COSV99290457; called by muse, mutect2, varscan2
- NFIX | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100666296; called by muse, mutect2
- NFKB1 | c.2027A>G p.D676G (on ENST00000394820 / NM_001382627.1; = p.D677G on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV99896724; called by muse, mutect2, varscan2
- NFKBIZ | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as rs746092557, COSV100396941; called by muse, mutect2, varscan2
- NFRKB | c.3706A>G p.N1236D (on ENST00000446488 / NM_001143835.2; = p.N1261D on NM_006165.3) | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1180321721, COSV100451799; called by muse, mutect2, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | catalogued as rs745904099; called by mutect2, pindel, varscan2
- NLGN4Y | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 148/178 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV100196417; called by muse, mutect2, varscan2
- NME1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs765050521, COSV99184000; called by muse, mutect2, varscan2
- NMT1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs955288678, COSV99364625; called by muse, mutect2, varscan2
- NMUR1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as rs745366125, COSV59404516; called by muse, mutect2, varscan2
- NOP56 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100249964; called by muse, mutect2, varscan2
- NOS2 | c.2013C>A p.S671R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as COSV100569502; called by muse, mutect2, varscan2
- NOTCH2 | c.4391C>T p.A1464V | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV56682739; called by muse, mutect2, varscan2
- NOTCH3 | c.5342A>T p.D1781V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99656074; called by muse, mutect2, varscan2
- NPAP1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV61510405; called by muse, mutect2, varscan2
- NPC1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99340913; called by muse, mutect2, varscan2
- NPY1R | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV99648514; called by muse, mutect2, varscan2
- NR4A1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs375396767, COSV99671064; called by muse, mutect2, varscan2
- NSD3 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV100388479; called by muse, mutect2, varscan2
- NSMAF | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99232408; called by muse, mutect2, varscan2
- NSRP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs572953048, COSV55936160; called by muse, mutect2, varscan2
- NT5C3B | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.468); catalogued as COSV99505065; called by muse, mutect2
- NTHL1 | c.563A>G p.Y188C (on ENST00000219066; = p.Y180C on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99526138; called by muse, mutect2, varscan2
- NTRK3 | c.1580A>G p.D527G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV58122878; called by muse, varscan2
- NUDCD2 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 151/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243521; called by muse, mutect2, varscan2
- NUDT17 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100492780; called by muse, mutect2, varscan2
- NUP210 | c.4483G>A p.A1495T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs199638243, COSV99595645; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 45/134 reads (34%) | catalogued as rs780417788; called by mutect2, varscan2
- NXNL2 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs780563117, COSV101018239; called by muse, mutect2, varscan2
- NYAP1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278357; called by muse, mutect2
- NYNRIN | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV101230514; called by muse, mutect2, varscan2
- OBSCN | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1237802265, COSV99473678; called by muse, mutect2, varscan2
- OR10R2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs200874337, COSV63769391; called by muse, mutect2, varscan2
- OR12D2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV101011127; called by muse, mutect2, varscan2
- OR2C3 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100825620; called by muse, mutect2, varscan2
- OR2T1 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822258; called by muse, mutect2, varscan2
- OR2T33 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 110/715 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751813840, COSV100531647; called by muse, mutect2, varscan2
- OR4C11 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100155219; called by muse, mutect2, varscan2
- OR4E2 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57731542; called by muse, mutect2
- OR5AR1 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100265579; called by muse, mutect2, varscan2
- OR5D16 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101003858; called by muse, mutect2, varscan2
- OR5L1 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61733414, COSV61735814; called by muse, mutect2, varscan2
- OR8B4 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV100635765; called by muse, mutect2, varscan2
- OR8H3 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV57909959; called by muse, mutect2
- OSBPL7 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs368110786; called by muse, mutect2, varscan2
- OSBPL7 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748431145, COSV50114378; called by muse, mutect2, varscan2
- OSCP1 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99347047; called by muse, mutect2, varscan2
- OTOA | c.1300G>A p.V434I (on ENST00000286149; = p.V420I on NM_144672.4) | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV99623743; called by muse, mutect2, varscan2
- P2RY13 | c.425T>C p.F142S | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99851742; called by muse, mutect2, varscan2
- PADI2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100970862; called by muse, mutect2, varscan2
- PANK1 | c.941G>T p.S314I (on ENST00000307534 / NM_148977.2; = p.S89I on NM_138316.4) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100285526; called by muse, mutect2, varscan2
- PARN | c.259T>G p.S87A | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs754319643, COSV100420687; called by muse, mutect2, varscan2
- PARP1 | c.2159T>A p.V720E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV100828786; called by muse, mutect2, varscan2
- PAX1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101270217; called by muse, mutect2, varscan2
- PBK | c.908A>T p.E303V | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV100107315; called by muse, mutect2, varscan2
- PCDH11X | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs753981444, COSV53500777; called by muse, mutect2
- PCDH12 | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99185908; called by muse, mutect2
- PCDH9 | c.3015G>T p.K1005N | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.277); catalogued as COSV60564469, COSV60590551; called by muse, mutect2, varscan2
- PCDHAC2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53859393, COSV99148275; called by muse, mutect2, varscan2
- PCDHB14 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.458); catalogued as COSV99505596; called by muse, mutect2, varscan2
- PCDHGA7 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs764454496, COSV54055472, COSV99531982; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCED1A | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs759246775, COSV62314322; called by muse, mutect2, varscan2
- PCNX2 | c.2042C>A p.S681Y | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99266260; called by muse, mutect2
- PCSK6 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083115; called by muse, mutect2, varscan2
- PDCD6IP | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 193/538 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV100218545; called by muse, mutect2, varscan2
- PDE7A | c.595G>T p.V199F (on ENST00000401827 / NM_001242318.3; = p.V173F on NM_002603.4) | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV101052611; called by muse, mutect2, varscan2
- PDS5A | c.1845G>T p.L615F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100337194; called by muse, mutect2, varscan2
- PDZD2 | c.5203G>T p.E1735* | Nonsense Mutation (SNP) | VAF 46/117 reads (39%) | catalogued as COSV56864793, COSV99223895; called by muse, mutect2, varscan2
- PEAK1 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100432508; called by muse, mutect2, varscan2
- PER3 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs772505358, COSV100728230; called by muse, mutect2, varscan2
- PER3 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1459720653, COSV100728231; called by muse, mutect2, varscan2
- PFN3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV99499465; called by muse, mutect2, varscan2
- PGGHG | c.1867A>C p.S623R | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV101164310; called by muse, mutect2, varscan2
- PHF2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1250567429, COSV100823048; called by muse, mutect2, varscan2
- PHF20L1 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 52/149 reads (35%) | catalogued as COSV55188987; called by muse, mutect2, varscan2
- PHRF1 | c.4523C>T p.P1508L (on ENST00000264555 / NM_001286581.2; = p.P1507L on NM_020901.4) | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52764420; called by muse, mutect2, varscan2
- PICK1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57634486; called by muse, mutect2, varscan2
- PIGZ | c.1467del p.T490Lfs*10 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs759867499; called by mutect2, pindel, varscan2
- PIGZ | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53014576; called by muse, mutect2, varscan2
- PKD2L1 | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100559306; called by muse, mutect2, varscan2
- PKD2L2 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99296038; called by muse, mutect2, varscan2
- PKLR | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs771218326, CD144491, COSV100712817; called by muse, mutect2, varscan2
- PKP4 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 70/110 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61578138; called by muse, mutect2, varscan2
- PLCXD1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as rs778878421, COSV101087804; called by muse, mutect2, varscan2
- PLD1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100577703; called by muse, mutect2, varscan2
- PLEK2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as rs753723077, COSV99371579; called by muse, mutect2, varscan2
- PLEKHM3 | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV101216304; called by muse, mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs746342377, COSV56183473; called by mutect2, varscan2
- PLXND1 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388658515, COSV60713787; called by muse, mutect2, varscan2
- PMCH | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100268183; called by muse, mutect2, varscan2
- PMFBP1 | c.2705A>G p.Q902R (on ENST00000537465; = p.Q897R on NM_031293.3) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99400302; called by muse, mutect2, varscan2
- POGLUT2 | c.1174T>C p.S392P | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101050761; called by muse, mutect2, varscan2
- POLD1 | c.347del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as COSV101486926; called by mutect2, pindel, varscan2
- POLR1H | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100198411; called by muse, mutect2, varscan2
- POM121L12 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101374855; called by muse, mutect2, varscan2
- POP4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1259772679, COSV55676547, COSV99694474; called by muse, mutect2
- POU2AF1 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV101260532; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2033C>G p.A678G | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV99460899; called by muse, mutect2, varscan2
- PPARGC1A | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV99337320; called by muse, mutect2
- PPEF2 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99714166; called by muse, mutect2, varscan2
- PPM1D | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs777279856, COSV59955025; called by muse, mutect2, varscan2
- PPP1R16B | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.044); catalogued as COSV100239045; called by muse, mutect2, varscan2
- PPP1R32 | c.4A>T p.M2L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV100087683; called by muse, mutect2, varscan2
- PPP1R3F | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs782769164, COSV50019286; called by muse, mutect2, varscan2
- PPP2R2A | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100277006; called by muse, mutect2, varscan2
- PREX2 | c.2774T>A p.I925N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV99905381; called by muse, mutect2, varscan2
- PRG2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142359007; called by muse, mutect2, varscan2
- PRPF39 | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1248578210, COSV100865982; called by muse, mutect2, varscan2
- PRRC2B | c.4712G>A p.R1571H | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61936697; called by muse, mutect2, varscan2
- PRRC2C | c.1708G>C p.E570Q (on ENST00000367742; = p.E568Q on NM_015172.4) | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.335); catalogued as COSV100144747; called by muse, mutect2, varscan2
- PRRC2C | c.4951T>C p.F1651L (on ENST00000367742; = p.F1649L on NM_015172.4) | Missense Mutation (SNP) | VAF 246/678 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100144749; called by muse, varscan2
- PSKH1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV99344502; called by muse, mutect2, varscan2
- PSMD11 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as rs1302226249, COSV99912340; called by muse, mutect2, varscan2
- PTBP1 | c.602A>G p.H201R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100608387; called by muse, mutect2, varscan2
- PTGER2 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99817323; called by muse, mutect2, varscan2
- PTGER3 | c.1170-1G>A p.X390_splice | Splice Site (SNP) | VAF 195/528 reads (37%) | catalogued as COSV100138369; called by muse, mutect2, varscan2
- PTGIS | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs754311420, COSV54840779; called by muse, mutect2, varscan2
- PTPN13 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV100364145; called by muse, mutect2, varscan2
- PTPN6 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356852472, COSV100016946; called by muse, mutect2, varscan2
- PTPRD | c.817del p.A273Qfs*4 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | catalogued as COSV61926373, COSV61949828; called by mutect2, pindel, varscan2
- PTPRH | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201369294, COSV99670740; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs768997455; called by mutect2, varscan2
- QRICH1 | c.1867C>A p.L623M | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100454941; called by muse, mutect2
- RAB3IP | c.803C>T p.T268M (on ENST00000550536 / NM_175623.4; = p.T252M on NM_022456.5) | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs575263311, COSV99922966; called by muse, mutect2, varscan2
- RAB42 | c.242dup p.V82Cfs*38 | Frame Shift Ins (INS) | VAF 29/80 reads (36%) | catalogued as rs753536519; called by mutect2, varscan2
- RALGAPA2 | c.3595A>C p.I1199L | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99173184; called by muse, mutect2, varscan2
- RALGAPB | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs138852733, COSV99484786; called by muse, mutect2, varscan2
- RANBP10 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100449143; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs773008500, COSV99622466; called by muse, mutect2, varscan2
- RAPGEF2 | c.2649A>T p.G883= | Splice Region (SNP) | VAF 70/183 reads (38%) | catalogued as COSV100030602; called by muse, mutect2, varscan2
- RASA3 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100479962; called by muse, mutect2, varscan2
- RASAL2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs764865700, COSV100862433; called by muse, varscan2
- RB1CC1 | c.4130G>A p.R1377H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs768037976, COSV99205489; called by muse, mutect2, varscan2
- RBM19 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1365747008, COSV99925602; called by muse, mutect2, varscan2
- RBM27 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99505762; called by muse, mutect2, varscan2
- RBM5 | c.1080T>A p.Y360* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100762168; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- RELA | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425736; called by muse, mutect2, varscan2
- REST | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100470713; called by muse, mutect2, varscan2
- REXO1 | c.1604T>C p.V535A | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99402049; called by muse, mutect2, varscan2
- RFPL2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1351536513, COSV50711612, COSV99964659; called by muse, mutect2, varscan2
- RHBDL2 | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100008325; called by muse, mutect2, varscan2
- RIC1 | c.3844G>A p.V1282I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs565348578, COSV99316725; called by muse, mutect2, varscan2
- RIMBP3 | c.2474del p.G825Afs*132 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs1318791353; called by mutect2, varscan2
- RIPK3 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs186368014, COSV53475147; called by muse, mutect2, varscan2
- RIPK3 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99352983; called by muse, mutect2, varscan2
- RNASE7 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100069652; called by muse, mutect2, varscan2
- ROCK1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101296249; called by muse, mutect2, varscan2
- RPE65 | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99253640; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL28 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs1375857394, COSV100689350; called by muse, mutect2, varscan2
- RPL9 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 245/605 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV99787581; called by muse, mutect2
- RPN2 | c.1614del p.T539Pfs*10 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as rs1426793158; called by mutect2, pindel, varscan2
- RPP38 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs138934702; called by muse, mutect2, varscan2
- RREB1 | c.3203T>C p.I1068T | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100619167; called by muse, mutect2, varscan2
- RRP12 | c.2275G>C p.A759P | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100212942, COSV59666989; called by muse, mutect2, varscan2
- RSF1 | c.2398del p.R800Efs*24 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as COSV57836485; called by mutect2, pindel, varscan2
- RSF1 | c.1763T>C p.L588S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1274843850, COSV100406933; called by muse, mutect2, varscan2
- RTL10 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs1157305088, COSV100144168; called by muse, mutect2, varscan2
- RTTN | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99731235; called by muse, mutect2, varscan2
- RUSC2 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV100770612; called by muse, mutect2, varscan2
- RUSF1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs185844277; called by muse, mutect2, varscan2
- RYR2 | c.13439T>A p.F4480Y | Missense Mutation (SNP) | VAF 320/769 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV100768316; called by muse, mutect2, varscan2
- RYR3 | c.4745G>A p.S1582N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1238658419, COSV66793261; called by muse, mutect2
- S1PR3 | c.1123A>T p.I375F | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.054); catalogued as rs1179229081, COSV100822472; called by muse, mutect2, varscan2
- SAFB2 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.622); catalogued as rs142026681; called by muse, mutect2, varscan2
- SALL1 | c.2690T>C p.V897A | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV99171610; called by muse, mutect2, varscan2
- SAR1A | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); catalogued as rs1304678978, COSV64699416; called by muse, mutect2, varscan2
- SARAF | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.705); catalogued as COSV99822659; called by muse, mutect2
- SBF1 | c.4136T>C p.V1379A | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100817514; called by muse, mutect2, varscan2
- SCAF1 | c.3232G>T p.V1078F | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100862056; called by muse, mutect2, varscan2
- SCAP | c.3703_3706del p.T1235Sfs*? | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs746678809; called by pindel, varscan2
- SCAP | c.1710dup p.S571Qfs*13 | Frame Shift Ins (INS) | VAF 51/150 reads (34%) | catalogued as rs1229536681; called by mutect2, pindel, varscan2
- SCARA3 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as COSV100106446; called by muse, mutect2
- SCN1A | c.4613T>C p.V1538A (on ENST00000303395 / NM_001202435.3; = p.V1527A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100319482; called by muse, varscan2
- SELENOI | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV99564230; called by muse, mutect2, varscan2
- SELENOV | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100112643; called by muse, mutect2
- SEMA4G | c.1379T>A p.V460D | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.055); catalogued as COSV99271997; called by muse, mutect2, varscan2
- SEMA6B | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs145507498; called by muse, mutect2, varscan2
- SEPTIN7 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV100621670; called by muse, mutect2, varscan2
- SESN2 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.253); catalogued as COSV99455427; called by muse, mutect2, varscan2
- SETBP1 | c.2890T>C p.F964L | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.083); catalogued as COSV99952234; called by muse, mutect2
- SETX | c.7437A>G p.I2479M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as COSV99808915; called by muse, mutect2, varscan2
- SF3B1 | c.1298C>G p.A433G | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV100133906; called by muse, varscan2
- SHANK2 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1555153814, COSV99572472; called by muse, mutect2, varscan2
- SHROOM1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs757897489, COSV100166966; called by muse, mutect2, varscan2
- SIAE | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99422205; called by muse, mutect2, varscan2
- SIM2 | c.1081T>C p.S361P | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs745663760, COSV99292920; called by muse, mutect2, varscan2
- SIPA1L2 | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV99477309; called by muse, mutect2, varscan2
- SIRPB1 | c.67del p.R23Dfs*13 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as COSV54374443; called by mutect2, pindel, varscan2
- SIRT1 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV99281614; called by muse, mutect2, varscan2
- SLAMF1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs757836091, COSV52499313; called by muse, mutect2, varscan2
- SLC17A9 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs752324785, COSV100947705; called by muse, mutect2, varscan2
- SLC22A7 | c.701T>C p.V234A (on ENST00000372585 / NM_153320.2; = p.V232A on NM_006672.3) | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101000769; called by muse, mutect2
- SLC25A1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99310883; called by muse, mutect2
- SLC25A22 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204111; called by muse, mutect2, varscan2
- SLC25A51 | c.243T>A p.Y81* | Nonsense Mutation (SNP) | VAF 48/148 reads (32%) | catalogued as COSV99643261; called by muse, mutect2, varscan2
- SLC26A5 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100098717, COSV59701016; called by muse, mutect2, varscan2
- SLC27A5 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs558863851, COSV54022023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A11 | c.595G>A p.G199R (on ENST00000345044 / NM_001024938.4; = p.G206R on NM_030807.5) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs144951215, COSV99741047; called by muse, mutect2, varscan2
- SLC2A13 | c.670A>C p.S224R | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99786010; called by muse, mutect2, varscan2
- SLC35E3 | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs778747700, COSV100097963; called by muse, mutect2, varscan2
- SLC35E4 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs755179385, COSV100299150; called by muse, mutect2, varscan2
- SLC36A3 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201585244, COSV58858430; called by muse, mutect2, varscan2
- SLC38A2 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99873760; called by muse, mutect2, varscan2
- SLC38A7 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV99543529; called by muse, mutect2, varscan2
- SLC41A1 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900337; called by muse, mutect2
- SLC46A1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1164744443, COSV100398034; called by muse, mutect2, varscan2
- SLC46A1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100398037; called by muse, mutect2, varscan2
- SLC4A2 | c.3275C>T p.T1092M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370805035; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 36/103 reads (35%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC5A9 | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99361383; called by muse, mutect2, varscan2
- SLC7A8 | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV100382185; called by muse, mutect2, varscan2
- SLC9A2 | c.1574T>G p.F525C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV99295904; called by muse, mutect2, varscan2
- SLC9C1 | c.2803A>G p.K935E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); catalogued as COSV59889275; called by muse, mutect2, varscan2
- SLCO1B3 | c.10C>A p.H4N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99680888; called by muse, mutect2, varscan2
- SLK | c.1369A>T p.I457L | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100211528; called by muse, mutect2, varscan2
- SLTM | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773584344, COSV100998568; called by muse, mutect2, varscan2
- SMAGP | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV101199374; called by muse, mutect2, varscan2
- SMARCC2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57223793; called by muse, mutect2, varscan2
- SMARCD3 | c.838C>T p.R280C (on ENST00000262188 / NM_001003801.2; = p.R267C on NM_003078.4) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1195534343, COSV99222804; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 108/284 reads (38%) | catalogued as rs1257129093; called by mutect2, varscan2
- SMC3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV62419019; called by muse, mutect2, varscan2
- SNAPC4 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100046858; called by muse, mutect2
- SNX19 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs1160487867, COSV99772835; called by muse, mutect2, varscan2
- SNX21 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs563427177, COSV99467378; called by muse, mutect2, varscan2
- SORCS3 | c.410del p.P137Qfs*32 | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | catalogued as rs1160073186; called by mutect2, pindel, varscan2
- SOS2 | c.3208C>T p.R1070W | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs760192938, COSV99365473; called by muse, mutect2, varscan2
- SPATA5L1 | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV99972851; called by muse, mutect2, varscan2
- SPATA5L1 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV99972852; called by muse, mutect2, varscan2
- SPI1 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99908682; called by muse, mutect2, varscan2
- SPICE1 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.087); catalogued as rs558422433, COSV99870942; called by muse, mutect2, varscan2
- SPRTN | c.1206T>A p.D402E | Missense Mutation (SNP) | VAF 127/281 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99149487; called by muse, mutect2, varscan2
- SRCAP | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99349418; called by muse, mutect2, varscan2
- SRCAP | c.4175C>A p.A1392D | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV99349419; called by muse, mutect2, varscan2
- SRFBP1 | c.778T>A p.Y260N | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100232649; called by muse, mutect2, varscan2
- SRR | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100026862; called by muse, mutect2
- SRRM1 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs866271152, COSV60480406; called by muse, mutect2, varscan2
- SRSF8 | c.100T>A p.F34I | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101475784; called by muse, mutect2, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | catalogued as rs752567808; called by mutect2, varscan2
- SSUH2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.651); catalogued as rs532787180, COSV100435607, COSV58029454; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | PolyPhen possibly damaging (0.643); catalogued as rs750135866, COSV100081826; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD7 | c.981T>A p.N327K | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.421); catalogued as COSV100474509; called by muse, mutect2, varscan2
- STK11 | c.314T>G p.L105* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100479729; called by muse, mutect2, varscan2
- STK17A | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100082023; called by muse, mutect2, varscan2
- STK36 | c.3115C>T p.R1039C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs751887210, COSV55325567; called by muse, mutect2, varscan2
- STRA8 | c.536C>T p.A179V (on ENST00000275764; = p.A157V on NM_182489.2) | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV51961717; called by muse, mutect2, varscan2
- STX1B | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287936; called by muse, mutect2, varscan2
- SUDS3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs779069152, COSV100819986; called by muse, mutect2, varscan2
- SULF2 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV100737018; called by muse, mutect2, varscan2
490 further variants in this file (219 protein-altering or splice-affecting, 249 silent, 22 other) are not listed here.
